Somatic mutation profile of tumor specimen TCGA-BR-8380-01A (aliquot TCGA-BR-8380-01A-11D-2340-08) from TCGA case TCGA-BR-8380, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.2 years (20,157 days).
Specimen TCGA-BR-8380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd2fff52-06c6-4fd0-95c6-7c25d28aa40e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8380-10A (Blood Derived Normal), aliquot TCGA-BR-8380-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f340c925-8358-44c0-bc9b-3bb22d00e636

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Frame Shift Ins 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3460G>A p.V1154I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs147794514; called by muse, mutect2, varscan2
- ALPK3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1172324544, COSV51936070; called by muse, mutect2
- APOB | c.12011C>A p.P4004Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51943225; called by muse, varscan2
- BRDT | c.338A>T p.D113V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62865960; called by muse, mutect2
- CBLC | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754761911, COSV54324298; called by muse, mutect2
- CD1A | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56863010, COSV99192721; called by muse, mutect2
- CELF2 | c.262G>A p.V88I (on ENST00000416382 / NM_001025077.3; = p.V95I on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs577233700, COSV59978327; called by muse, mutect2, varscan2
- DDX4 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs777699581, COSV61754161, COSV61755159; called by muse, mutect2, varscan2
- DNAH5 | c.9821C>G p.S3274C | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV54238539, COSV54243980; called by muse, mutect2, varscan2
- EIF2AK4 | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.101); catalogued as rs1221590907, COSV55475205; called by muse, mutect2
- FAM71A | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1406397882, COSV54236308; called by muse, mutect2, varscan2
- FBXO10 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.203); catalogued as COSV52834173; called by muse, mutect2
- FNDC11 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as rs776604532, COSV64443127; called by muse, mutect2, varscan2
- GATA3 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60517884; called by muse, mutect2
- HEPACAM2 | c.14C>G p.A5G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV66747947; called by muse, mutect2
- HOXA1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); catalogued as rs762135120, COSV56067147; called by muse, mutect2
- HOXD10 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV50901170; called by muse, mutect2
- HTR1A | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60501829; called by muse, mutect2
- LRRC37A3 | c.3260T>C p.I1087T | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1367039518, COSV58536032; called by muse, mutect2, varscan2
- NOX5 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs773013901, COSV52992347, COSV99533788; called by muse, mutect2, varscan2
- OFD1 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.54); catalogued as COSV100407073; called by muse, mutect2
- OR5T2 | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs867798059, COSV57588098; called by muse, mutect2, varscan2
- PAPPA2 | c.3224A>C p.K1075T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV62796506; called by muse, mutect2, varscan2
- RCBTB1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51635601; called by muse, mutect2, varscan2
- RYR2 | c.9667G>A p.E3223K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs556291797, COSV63684905, COSV63711474; called by muse, mutect2, varscan2
- SELP | c.2055C>G p.S685R | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55254801; called by muse, mutect2, varscan2
- SEPTIN9 | c.272G>A p.R91Q (on ENST00000427177 / NM_001113491.2; = p.R73Q on NM_006640.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); catalogued as rs764983438, COSV61201901; called by muse, mutect2, varscan2
- SMARCD3 | c.1408C>T p.R470C (on ENST00000262188 / NM_001003801.2; = p.R457C on NM_003078.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs753343590, COSV50394126; called by muse, mutect2, varscan2
- SMG6 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs756932495, COSV53971149; called by muse, mutect2, varscan2
- SPAG16 | c.1698T>G p.N566K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59106886; called by muse, mutect2
- SPPL2C | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.273); catalogued as COSV61293133; called by muse, mutect2, varscan2
- SRRM2 | c.4478C>G p.P1493R | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV57076829; called by muse, mutect2, varscan2
- ST14 | c.2480dup p.D828Rfs*70 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | catalogued as rs1301353663; called by mutect2, pindel, varscan2
- ST6GALNAC4 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | PolyPhen benign (0.026); catalogued as rs749985360, COSV59130203; called by muse, mutect2, varscan2
- TACR3 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59204478; called by muse, mutect2, varscan2
- TBC1D8 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564042549, COSV65214165; called by muse, mutect2
- TMCO4 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99617342; called by muse, mutect2, varscan2
- TPPP3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as rs372034237; called by muse, mutect2
- TSHR | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369995834; called by muse, mutect2
- TTLL13P | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373623804, COSV60038913; called by muse, mutect2, varscan2
- VEGFD | c.13T>A p.W5R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV52910319; called by muse, mutect2, varscan2
- WDR19 | c.2730A>C p.R910S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV56467489; called by muse, mutect2
- WNT7B | c.978C>A p.C326* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV59751077; called by muse, mutect2, varscan2
- ZNF14 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs573777738, COSV59849404; called by mutect2, varscan2
- ZNF479 | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100482973; called by mutect2, varscan2
- ZNF548 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60241420; called by muse, mutect2, varscan2
- ZNF696 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV57525382; called by muse, mutect2
- CNOT3 | c.276dup p.V93Sfs*51 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- DDX27 | c.2308G>C p.E770Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.198); called by mutect2, varscan2
- HEATR4 | c.2260G>T p.G754C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MDGA1 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SOX9 | c.662_663dup p.H222Cfs*32 | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- UEVLD | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- DCAF12L1 | c.849C>T p.D283= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1442541200, COSV64421870; called by muse, mutect2, varscan2
- DCAF6 | c.1365A>G p.T455= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV56581536; called by muse, mutect2
- E4F1 | c.2115G>A p.A705= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1227889379, COSV57040029; called by muse, mutect2, varscan2
- FBXO44 | c.66C>T p.P22= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs770859002, COSV52354762; called by mutect2, varscan2
- FCGBP | c.10323C>T p.C3441= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs530920778; called by muse, mutect2, varscan2
- FGF23 | c.540C>T p.S180= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV52975925, COSV52976963; called by muse, mutect2, varscan2
- GAB4 | c.460A>C p.R154= | Silent (SNP) | VAF 16/181 reads (9%) | catalogued as COSV68754436; called by muse, mutect2
- GIPC1 | c.429C>T p.L143= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs767290686, COSV61774869; called by muse, mutect2, varscan2
- HSPA2 | c.1338C>T p.Y446= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV55970622; called by muse, mutect2, varscan2
- MINK1 | c.1758G>A p.R586= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV61791373; called by muse, mutect2
- OR7D2 | c.561G>T p.L187= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV60140517; called by muse, mutect2
- OR9G4 | c.270G>A p.K90= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs778698853, COSV57248501; called by muse, mutect2, varscan2
- PAPPA2 | c.2877C>T p.H959= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV62803788; called by muse, mutect2
- POLD1 | c.2088C>T p.S696= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs1060504359, COSV70956147; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBPL2 | c.48G>A p.P16= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV55973079; called by muse, mutect2, varscan2
- ZCCHC3 | c.1063A>C p.R355= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV66643483; called by muse, mutect2
- ASIC2 | c.556-179403G>C | Intron (SNP) | VAF 6/43 reads (14%) | catalogued as rs1432080665, COSV99860872; called by muse, mutect2, varscan2
